Somatic mutation profile of tumor specimen TCGA-4G-AAZT-01A (aliquot TCGA-4G-AAZT-01A-11D-A417-09) from TCGA case TCGA-4G-AAZT, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.4 years (22,777 days).
Specimen TCGA-4G-AAZT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e12dec8-f61e-4e21-a485-8ecad1f39279.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4G-AAZT-10A (Blood Derived Normal), aliquot TCGA-4G-AAZT-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41975865-b720-4308-aaec-7ef476be4fc8

The open-access MAF lists 39 somatic variants for this specimen: 32 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 26, Silent 7, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ETV5 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1276673113, COSV100111883; called by muse, mutect2
- FMN2 | c.3992T>A p.L1331* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as COSV60429626; called by muse, mutect2, varscan2
- FMNL1 | c.2885C>T p.T962M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs750004915; called by muse, mutect2, varscan2
- LRP1 | c.7574G>A p.R2525Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs143045870; called by muse, varscan2
- LTN1 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100798200, COSV63735476; called by muse, mutect2, varscan2
- PAX3 | c.141C>A p.N47K | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as CM961088; called by muse, mutect2, varscan2
- PBRM1 | c.1600C>T p.R534* | Nonsense Mutation (SNP) | VAF 3/25 reads (12%) | catalogued as COSV56261082; called by muse, mutect2
- RYR1 | c.9679C>T p.R3227W | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765250427, COSV62099895; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC26A7 | c.710G>A p.S237N | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs778212161, COSV52601142; called by muse, mutect2, varscan2
- TICAM1 | c.1874C>T p.P625L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs760042063; called by muse, mutect2, varscan2
- ADAM32 | c.2053C>A p.L685I | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.338); called by muse, mutect2
- ARID1A | c.3540-5_3555del p.X1180_splice | Splice Site (DEL) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- CAPN12 | c.857G>A p.G286D | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CHL1 | c.3146C>G p.T1049S (on ENST00000397491 / NM_001253387.1; = p.T1065S on NM_006614.4) | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DPYSL4 | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELF3 | c.58_71del p.S20Hfs*15 | Frame Shift Del (DEL) | VAF 13/30 reads (43%) | called by mutect2, pindel, varscan2
- FBN2 | c.5615G>T p.G1872V | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- GNA15 | c.781A>G p.I261V | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2
- KATNAL2 | c.287C>T p.T96I (on ENST00000356157 / NM_001353899.1; = p.T24I on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NUP210 | c.3184A>C p.N1062H | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- NYAP2 | c.1481C>T p.T494I | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- PHIP | c.3052C>G p.L1018V | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- PLCB1 | c.1573A>C p.M525L | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXNA4 | c.2343G>C p.L781F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RHOBTB3 | c.1060T>G p.W354G | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2
- RSC1A1 | c.1179del p.D394Tfs*36 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- SCN4A | c.4129C>T p.Q1377* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2
- STAB2 | c.5366C>T p.A1789V | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, varscan2
- VAPB | c.541C>A p.Q181K | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.88); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- WIZ | c.4715T>G p.L1572R (on ENST00000673675 / NM_001371589.1; = p.L477R on NM_021241.3) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- ZDHHC17 | c.566A>G p.N189S | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- FLG | c.3438C>T p.H1146= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as rs769215947; called by muse, mutect2, varscan2
- ISLR2 | c.372G>A p.A124= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs780206482, COSV62301549; called by mutect2, varscan2
- KCNU1 | c.3051G>T p.V1017= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV67755960; called by muse, mutect2, varscan2
- MYH2 | c.1536G>A p.T512= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as rs146376676; called by muse, mutect2, varscan2
- NID1 | c.978C>T p.Y326= | Silent (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- NLRX1 | c.1893C>G p.L631= | Silent (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- PCDHA4 | c.1869C>T p.R623= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs782158159, COSV63543046; called by muse, mutect2, varscan2
